MMRF case MMRF_1450 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/735e67ee-112b-44aa-8c5e-5094954b7468

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 69 years; Vital status: Dead; Days to death: 16 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.7 years (25,463 days); ISS stage: II; Days to last known disease status: 16 days; Days to last follow up: 16 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 16 days.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -12, day 16.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Calcium 2.18 mmol/L.
- Immunoglobulin G 15.6 g/L.
- Lactate Dehydrogenase 5.65 µkat/L.
- Serum Free Immunoglobulin Light Chain, Lambda 0.972 mg/dL.
- Beta 2 Microglobulin 2.34 µg/mL.
- Immunoglobulin M 0.23 g/L.
- Creatinine 46.9 µmol/L.
- Albumin 30 g/L.
- Serum Free Immunoglobulin Light Chain, Kappa 547 mg/dL.
- Platelets 494 ×10⁹/L.
- Leukocytes 8.4 ×10⁹/L.
- Glucose 4.9 mmol/L.
- Immunoglobulin A 0.47 g/L.
- Hemoglobin 5.52 mmol/L.
- Absolute Neutrophil 6.4 ×10⁹/L.
- C-Reactive Protein 3.04 mg/dL.
- Total Protein 6 g/dL.
- Blood Urea Nitrogen 2.86 mmol/L.
- M Protein 1.12 g/dL.

Other clinical attributes
- Day -12: Weight: 99 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_1450_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1450_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
